Surgical pathology report (de-identified scan), TCGA case TCGA-MA-AA3W, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-MA-AA3W-01A (Primary Tumor).

[page 1 of 6]
Results

SURGICAL PATHOLOGY

Entry Date

Component Results

Component

Surgical Pathology

(note)

Location

SURGICAL PATHOLOGY

Accession #:

Collected:

Received:

ICD-O-3
Carcinoma, squamous cell NOS
8070/3
Site Cervix NOS
C53.9
XD 4/11/14

PATHOLOGIC DIAGNOSIS

A. LYMPH NODE, LEFT PARAMETRIAL, BIOPSY:

- ONE LYMPH NODE WITH NO EVIDENCE MALIGNANCY (0/1)

B. UTERUS, CERVIX, RADICAL HYSTERECTOMY:

- INVASIVE POORLY DIFFERENTIATED CERVICAL SQUAMOUS CARCINOMA pT1b2N1
- TUMOR EXTENDS INTO LOWER UTERINE SEGMENT
- TUMOR NOT PRESENT AT INKED MARGINS
- LYMPHOVASCULAR SPACE INVASION IDENTIFIED
- PERINEURAL INVASION IDENTIFIED
- FOCAL SQUAMOUS CARCINOMA IN-SITU
- FOURTEEN LYMPH NODES WITH NO EVIDENCE OF MALIGNANCY (0/14)

UTERUS, ENDOMETRIUM, RADICAL HYSTERECTOMY:

- INACTIVE TO ATROPHIC ENDOMETRIUM
- TUBAL METAPLASIA

UTERUS, MYOMETRIUM, HYSTERECTOMY:

- EXTENSION OF CERVICAL POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA INTO LOWER UTERINE SEGMENT
- ARTERY WITH MEDIAL CALCIFIC SCLEROSIS

FALLOPIAN TUBE, RIGHT, SALPINGECTOMY:

- PARATUBAL CYST

OVARY, RIGHT, OOPHORECTOMY:

- NO SPECIFIC PATHOLOGIC ALTERATION

C. LYMPH NODE, LEFT PARAMETRIUM, BIOPSY:

- ONE LYMPH NODE WITH METASTATIC CARCINOMA (1/1)

D. SOFT TISSUE, LEFT PARAMETRIUM, BIOPSY:

- ONE LYMPH NODE WITH NO EVIDENCE MALIGNANCY (0/1)

E. FALLOPIAN TUBE AND OVARY, LEFT, SALPINGO-OOPHORECTOMY:

- BENIGN INCLUSION CYST

F. SOFT TISSUE, VAGINAL MARGIN, LEFT, EXCISION:

[page 2 of 6]
[REDACTED]

- FIBROVASCULAR TISSUE WITH NO SIGNIFICANT HISTOPATHOLOGIC ALTERATION

G. LYMPH NODE, LEFT PELVIC, DISSECTION:

- SIX LYMPH NODES WITH NO EVIDENCE MALIGNANCY (0/6)

H. LYMPH NODE, LEFT PELVIC, BIOPSY:

- NO LYMPH NODES SEEN
- BENIGN FIBROADIPOSE TISSUE WITH NO EVIDENCE OF MALIGNANCY

I. LYMPH NODE, RIGHT PELVIC, DISSECTION:

- SEVENTEEN LYMPH NODES WITH NO EVIDENCE MALIGNANCY (0/17)

"I have personally reviewed the resident's preliminary interpretation and all specimen preparations and have personally issued this report."

Comment
Specimen
Cervix
Uterine corpus

Procedure
Radical hysterectomy

Tumor Size
Greatest dimension: 4.1cm
Additional dimensions: 2 cm

Tumor Site
Left superior quadrant (12 to 3 o'clock)
Left inferior quadrant (3 to 6 o'clock)
Right inferior quadrant (6 to 9 o'clock)
Right superior quadrant (9 to 12 o'clock)

Histologic Type (select all that apply)
Squamous cell carcinoma
Nonkeratinizing

Histologic Grade
G3: Poorly differentiated

Margins
Margins uninvolved by invasive carcinoma

Lymph-Vascular Invasion
Present

Pathologic Staging

Primary Tumor
pT1 [I]: Cervical carcinoma confined to uterus
pT1b2 [IB2]: Clinically visible lesion >4.0 cm in greatest dimension

Regional Lymph Nodes (pN)
pN1: Regional lymph node metastasis

Number of Lymph Nodes Examined
Specify: 40

[page 3 of 6]
Number of Lymph Nodes Involved
Specify: 1

Distant Metastasis (pM)
Not applicable

Additional Pathologic Findings (select all that apply)
None identified

Intraoperative Consultation
Intraoperative Consultation Diagnosis:
FSA1: Lymphoid tissue, negative for tumor.
- Verbally reported to

Staff Pathologist

Pathology Resident

Pertinent Clinical Information
Pertinent History/Operative Findings: Cervical cancer.

A. Lymph Node / left parametrial #1; B. Uterus, Cervix; C. Lymph Node / left portion parametrium #2, D. Soft Tissue /right parametrium biopsy; E. Tube and ovary, L; F. Vaginal margin , left; G. Lymph Node , left pelvic; H. Lymph Node , distal left pelvic; I. Lymph Node , right pelvic.

Gross Description

The specimen is received in nine parts, each labeled with the patient's name and medical record number.

Part A: Received fresh and labeled "LEFT PARAMETRIAL NODE" is a 1.0 x 0.8 x 0.2 cm pink-tan rubbery portion of soft tissue, which is submitted in toto for frozen section as FSA1.

Part B: Received fresh and labeled "UTERUS AND CERVIX" is a 114 gram uterus with attached cervix, vaginal cuff margin, and right fallopian tube and ovary. The uterine body measures 4.8 x 4.5 x 3.3 cm, and the attached cervix and vaginal cuff measure 2.6 x 4.5 x 3.2 cm. The vaginal cuff margin is pink-tan, smooth and glistening, and the cervix is tan-brown to tan-red and bosselated and displays an ill-defined os measuring 0.5 cm in diameter. A representative section of the cervix at the 1 to 2 o'clock location is submitted for the research study. The anterior vaginal cuff lower uterine segment margin is inked blue and the posterior vaginal cuff lower uterine segment margin is inked black and the vaginal cuff margin is removed en face and submitted as follows:

B1: 12 to 3 o'clock

B2: 3 to 6 o'clock

B3: 6 to 9 o'clock

B4: 9 to 12 o'clock

The uterus is bisected to reveal a poorly demarcated squamocolumnar junction and a lobulated tan-brown endocervical canal. Grossly the tumor is circumferential and invades for a depth extending from the cervical lip into the myometrium for a distance of 4.1 cm, and for a width from the endocervical mucosa to the uterine soft tissue margin of 2.0 cm. The endometrium is tan-pink and velvety and measures 0.2 cm in thickness and the myometrium is pink-tan and rubbery and measures up to 1.7 cm in thickness on

[page 4 of 6]
the anterior wall and 1.4 cm in thickness on the posterior wall.

Representative sections of the cervix and endocervical canal are submitted as follows:

B5-B6: 12 o'clock cervix to lower uterine segment, proximal end inked green
B7-B8: 3 o'clock
B9-B10: 6 o'clock
B11-B13: 9 o'clock
B14-B16: anterior lower uterine segment
B17: anterior endomyometrium
B18-B20: posterior lower uterine segment
B21: posterior endomyometrium
B22-B23: left parametrium
B24-B27: right parametrium

The attached right fallopian tube is pink-tan with a delicate fimbriated end and measures 5.6 cm in length and ranges in diameter from 0.5 to 0.3 cm. The fallopian tube is adhered to a tan-yellow bosselated ovary measuring 2.5 x 1.6 x 1.0 cm. The fallopian tube is serially cross sectioned to reveal a pinpoint lumen. The ovary is bisected to reveal a tan-white homogenous cut surface with tan-white corpus albicans. Representative sections are submitted as follows:

B28: ovary
B29: fallopian tube with attached ovary

Gross photographs are obtained.

Part C: Received in formalin and labeled "LEFT PARAMETRIUM #2" are two tan-pink rubbery portions of soft tissue measuring 0.7 x 0.3 x 0.3 cm and 0.3 x 0.2 x 0.2 cm. The specimen is submitted in toto in cassette C1.

Part D: Received in formalin and labeled "RIGHT PARAMETRIUM" is a pink-tan rubbery portion of soft tissue measuring 1.0 x 0.7 x 0.3 cm. The specimen is submitted in toto in cassette D1.

Part E: Received in formalin and labeled "LEFT OVARY AND FALLOPIAN TUBE" is a pink-tan fallopian tube measuring 4.0 x 0.6 x 0.5 cm. The fallopian tube displays a delicate fimbriated end with an attached tan-yellow bosselated ovary measuring 3.0 x 1.5 x 1.4 cm. The fallopian tube is serially cross sectioned to reveal a stellate lumen. The ovary is bisected to reveal tan-pink to tan-white parenchyma with tan-white corpus albicans. The ovarian capsule adjacent to the ovarian ligament displays a 0.4 cm in diameter cyst containing clear serous fluid. The walls are twp, smooth and glistening, with no papillary excrescences. Representative sections are submitted as follows:

E1: fallopian tube
E2: portion of ovary with cyst
E3: cross section of ovary

Part F: Received in formalin and labeled "LEFT VAGINAL MARGIN" is a tan-pink rubbery portion of soft tissue with overlying mucosa measuring 2.1 x 1.0 cm, excised to a depth of 0.6 cm. No orientation is provided. The specimen is bisected along the longitudinal axis to reveal pink-white cut surfaces. The tissue is submitted in its entirety in cassettes F1 and F2.

Part G: Received in formalin and labeled "LEFT PELVIC LYMPH NODE" are multiple golden-yellow fibrofatty portions of tissue, and a laparoscopic sac containing additional portions of tissue, 5.0 x 4.6 x 1.3 cm in aggregate. The tissue is dissected for lymph nodes and reveals thirteen possible lymph nodes which are submitted as follows:

[page 5 of 6]
G1: nine possible lymph nodes
G2: two possible lymph nodes
G3: one lymph node bisected
G4-G5: one lymph node

Part H: Received in formalin and labeled "DISTAL LEFT PELVIC LYMPH NODE" is a golden-yellow fibrofatty portion of tissue measuring 0.2 x 0.2 x 0.1 cm. The specimen is submitted in toto in cassette H1.

Part I: Received in formalin and labeled "RIGHT PELVIC LYMPH NODE" are multiple golden-yellow fibrofatty portions of tissue measuring 5.8 x 5.5 x 1.5 cm. The tissue is dissected for lymph nodes and reveal twenty-one lymph nodes, which are submitted as follows:

I1: four lymph nodes
I2: six lymph nodes
I3: six lymph nodes
I4: three lymph nodes
I5: one lymph node bisected
I6: one lymph node bisected

Pathologists' Assistant

Microscopic Description
A-I: Performed.

Pathology Resident
Electronically Signed Out

Staff Pathologist

Result History

SURGICAL PATHOLOGY (Order on - Order Result History Report.

Lab Information

Resulting Lab

Order Information

Order Date Order Time

Result Information

Result Date and Time Status Priority
Final result Routine

Received Date/Time

Received Date Received Time

Order Providers

Authorizing Provider Encounter Provider

Encounter

View Encounter

[page 6 of 6]
Order**SURGICAL PATHOLOGY****(Order****Administration Details**No Administrations
Recorded**Order Information**

Order Date/Time

Release Date/Time

Start Date/Time

End Date/Time

Order DetailsFrequency
ONCEDuration
1 occurrencePriority
RoutineOrder Class
Normal**Quantity**Ordering Quantity
1**Original Order**

Ordered On

Ordered By

Transfer Service**Collection Information**

Collection Date

Collection Time

Resulting Agency

Provider Information

Ordering User

Authorizing Provider

Attending Provider(s)

Order-Level Documents:

There are no order-level documents.

Encounter[View Encounter](#)**Orders Needing Specimen Collection****** None ****

Source: NCI Genomic Data Commons file a1e2246a-92ed-4217-812f-b2da433d5125 (TCGA-MA-AA3W.1C91223A-5529-46CD-AA9C-40A974F1843E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).